Gene-level copy-number profile of tumor specimen ALCH-ADN7-TTP1-A from ALCHEMIST case ALCH-ADN7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.0 years (21,567 days).
Specimen ALCH-ADN7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bdbec718-0558-4b3b-9f5a-80df97a5e341.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADN7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/27bcadd7-d8c0-4fd8-bfe0-2a5c7aac40c0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 6,724; copy number 2: 34,906; copy number 3: 14,050; copy number 4: 2,043; copy number 5: 327; copy number 6: 196; copy number 7: 3; copy number 8: 9; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:231,713,314–231,713,398, 1 gene: MIR1244-1.
- chr3:48,599,002–48,621,769, 2 genes: UQCRC1, TMEM89.
- chr3:48,663,776–48,672,733, 2 genes: LINC02585, AC141002.1.
- chr3:51,957,454–51,995,895, 7 genes (within-gene range 0–1): PCBP4, AC115284.1, ABHD14B, ABHD14A, ABHD14A-ACY1, ACY1, RPL29.
- chr7:76,173,733–76,516,522, 11 genes: AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr8:144,720,907–144,853,736, 8 genes: ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr13:113,008,778–113,010,319, 2 genes (within-gene range 0–2): AL356740.2, AL356740.3.
- chr13:113,339,450–113,339,958, 1 gene (within-gene range 0–1): AL136221.1.
- chr15:25,178,738–25,257,027, 41 genes (within-gene range 0–2): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:41,825,099–41,827,936, 1 gene (within-gene range 0–3): AC020659.2.
- chr16:29,613,103–29,636,328, 3 genes: SLC7A5P1, CA5AP1, AC009086.1.
- chr17:3,923,870–3,981,899, 2 genes: ATP2A3, LINC01975.
- chr17:29,560,547–29,567,037, 1 gene (within-gene range 0–3): ABHD15.
- chr17:29,566,052–29,614,761, 5 genes (within-gene range 0–3): TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4.
- chr19:11,435,284–11,559,236, 11 genes (within-gene range 0–1): PRKCSH, ELAVL3, AC008481.3, ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1, CNN1, ELOF1.
- chr19:11,574,660–11,579,008, 1 gene (within-gene range 0–1): ACP5.
- chr19:41,956,879–41,997,497, 2 genes (within-gene range 0–1): AC010616.1, ATP1A3.
- chr19:42,297,033–42,390,297, 6 genes: PAFAH1B3, PRR19, TMEM145, MEGF8, MIR8077, CNFN.
- chr20:30,214,765–30,214,976, 1 gene: CFTRP3.
- chr21:43,363,332–43,427,131, 2 genes: AP001046.1, SIK1.
- chr22:21,045,960–21,064,168, 1 gene: LRRC74B.
- chr22:23,510,154–23,513,602, 2 genes: AP000345.3, LINC02557.
- chr22:29,711,820–29,719,714, 1 gene (within-gene range 0–1): AC004882.2.
- chr22:30,607,003–30,627,271, 1 gene (within-gene range 0–1): TCN2.
- chr22:41,229,510–41,240,931, 1 gene (within-gene range 0–1): CHADL.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 537 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,308,597–1,328,896, 5 genes, copy number 6 (within-gene range 3–6): PUSL1, INTS11, MIR6727, AL139287.1, CPTP.
- chr8:95,947,781–103,230,305, 161 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:103,154,614–103,154,689, 1 gene, copy number 6: MIR3151.
- chr8:108,162,787–108,443,496, 1 gene, copy number 5 (within-gene range 3–5): EIF3E.
- chr8:108,378,831–108,787,594, 6 genes, copy number 5: RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1.
- chr8:123,041,968–125,367,120, 63 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:131,904,093–134,390,487, 38 genes, copy number 5: EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1.
- chr8:135,742,343–135,742,495, 1 gene, copy number 6: RNU1-35P.
- chr8:138,130,023–142,545,009, 51 genes, copy number 5–6: FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1.
- chr16:1,826,941–1,884,294, 4 genes, copy number 5 (within-gene range 4–5): FAHD1, MEIOB, AL031722.1, LINC00254.
- chr19:31,787,148–33,589,688, 49 genes, copy number 5: RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131.
- chr19:34,837,889–34,964,229, 9 genes, copy number 8: AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6, ZNF792.
- chr19:36,510,687–38,208,369, 58 genes, copy number 6 (within-gene range 1–6): ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1.
- chr20:52,192,159–55,075,140, 33 genes, copy number 6 (within-gene range 2–6): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4.
- chr20:59,577,509–60,653,784, 10 genes, copy number 5–9 (within-gene range 4–9): PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG.
- chr20:60,414,396–60,814,211, 5 genes, copy number 5–7: MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1.
- chr20:62,231,922–62,937,952, 42 genes, copy number 5: OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1.

Autosomal genes at a single copy (total copy number 1): 6,375. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
